Somatic mutation profile of tumor specimen TCGA-EO-A3AY-01A (aliquot TCGA-EO-A3AY-01A-12D-A19Y-09) from TCGA case TCGA-EO-A3AY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.3 years (21,291 days).
Specimen TCGA-EO-A3AY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae221750-d7ff-4784-a358-cabf87eb9bef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A3AY-10A (Blood Derived Normal), aliquot TCGA-EO-A3AY-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69c3bd30-bc94-4a41-8b9d-96e23844f568

The open-access MAF lists 3,811 somatic variants for this specimen: 3,094 protein-altering or splice-affecting, 603 silent, 114 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,570, Silent 603, Nonsense Mutation 451, Intron 47, Splice Site 47, RNA 33, Splice Region 15, 3'UTR 11, 5'Flank 9, 3'Flank 8, 5'UTR 6, Frame Shift Ins 6.

Variants (750 of 3,811; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as rs886041791, COSV99967848; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 32/97 reads (33%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 74/98 reads (76%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.7792C>T p.R2598* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as rs138941496, CM960105, COSV53725297, COSV99588934; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2451C>A p.F817L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs934266733, COSV59480834; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV51649761; called by muse, mutect2, varscan2
- CASK | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1114167352, COSV59364220; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- DDX3X | c.1579C>T p.R527C (on ENST00000399959; = p.R528C on NM_001356.5) | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1064795323, COSV67863221; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1178187217, COSV100176009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DYRK1A | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs797045041, COSV58292419; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1387T>C p.S463P | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.963); catalogued as rs1057519714, COSV52784970; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8326C>T p.R2776* | Nonsense Mutation (SNP) | VAF 61/139 reads (44%) | catalogued as rs137854466, CM940772, COSV57312804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GABRG2 | c.937G>T p.G313* (on ENST00000361925 / NM_001375343.1; = p.G273* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 85/248 reads (34%) | catalogued as rs1469287853, COSV100729336, COSV62721530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs782396605, COSV68683552; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- OPA1 | c.1261C>T p.R421* (on ENST00000361510 / NM_130837.3; = p.R366* on NM_015560.3) | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | catalogued as rs104893753, CM002638, COSV62479865, COSV62483194; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1635G>C p.E545D | Missense Mutation (SNP) | VAF 28/100 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as rs121913275, COSV55874040, COSV55875881, COSV55956933; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1381C>T p.R461* (on ENST00000521381 / NM_181523.3; = p.R191* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as rs1057519838, COSV57125001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 40/114 reads (35%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, varscan2
- SCN1A | c.5674C>T p.R1892* (on ENST00000303395 / NM_001202435.3; = p.R1881* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as rs794726739, CM024313, CM162662, COSV100318718; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | catalogued as rs201287466, COSV62929985; called by muse, mutect2, varscan2
- AADACL4 | c.198C>A p.C66* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as COSV100879323; called by muse, mutect2, varscan2
- AADACL4 | c.346A>C p.I116L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV100879325, COSV66106178; called by muse, mutect2, varscan2
- AADAT | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV100528530; called by muse, mutect2, varscan2
- AARS1 | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1329226456, COSV99933099; called by muse, mutect2, varscan2
- ABCA1 | c.6500T>C p.V2167A | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV101036292; called by muse, mutect2, varscan2
- ABCA1 | c.2945A>G p.N982S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101036293; called by muse, mutect2, varscan2
- ABCA10 | c.3627G>T p.K1209N | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99287573; called by muse, mutect2, varscan2
- ABCA10 | c.1963G>T p.E655* | Nonsense Mutation (SNP) | VAF 52/171 reads (30%) | catalogued as COSV99287574; called by muse, mutect2, varscan2
- ABCA10 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 27/79 reads (34%) | catalogued as rs1568065104, COSV52219089, COSV52231354, COSV99288594; called by muse, mutect2, varscan2
- ABCA12 | c.3640A>G p.T1214A (on ENST00000272895 / NM_173076.3; = p.T896A on NM_015657.3) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99787534; called by muse, mutect2, varscan2
- ABCA13 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV101329875; called by muse, mutect2, varscan2
- ABCA13 | c.8253G>T p.K2751N | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.842); catalogued as COSV101446689; called by muse, mutect2, varscan2
- ABCA13 | c.9307A>C p.I3103L | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV101446690; called by muse, mutect2, varscan2
- ABCA13 | c.13598G>A p.R4533H | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747899889, COSV68944659; called by muse, mutect2, varscan2
- ABCA6 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs771243934, COSV52641606, COSV99447676; called by muse, mutect2, varscan2
- ABCA9 | c.4709A>C p.K1570T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100382487; called by muse, mutect2
- ABCB1 | c.2581C>A p.L861I | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.675); catalogued as COSV99711731; called by muse, mutect2, varscan2
- ABCB1 | c.2278C>A p.L760I | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV99711734; called by muse, mutect2, varscan2
- ABCB1 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99711737; called by muse, mutect2, varscan2
- ABCB1 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1390637727, COSV55944962; called by muse, mutect2, varscan2
- ABCB4 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | catalogued as CM075940, COSV55938003; called by muse, mutect2, varscan2
- ABCC12 | c.1377G>T p.Q459H | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100251968; called by muse, mutect2, varscan2
- ABCC2 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763988128, COSV64984835; called by muse, mutect2, varscan2
- ABCC3 | c.1473G>T p.M491I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as COSV99558460; called by muse, mutect2, varscan2
- ABCC3 | c.4567G>T p.D1523Y | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104374422, COSV99558463; called by muse, mutect2, varscan2
- ABCC4 | c.2772G>T p.Q924H | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100972147; called by muse, mutect2, varscan2
- ABCC4 | c.2106G>T p.K702N | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100972148; called by muse, mutect2, varscan2
- ABCC4 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100972150; called by muse, mutect2, varscan2
- ABCC5 | c.1108A>C p.M370L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV99656174; called by muse, mutect2
- ABCC9 | c.3397C>A p.P1133T | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV99683862; called by muse, mutect2, varscan2
- ABCC9 | c.3121A>G p.I1041V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99683869; called by muse, mutect2, varscan2
- ABCC9 | c.1654C>A p.L552I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV53963652, COSV99683873; called by muse, mutect2, varscan2
- ABCD1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs782723351, COSV54383490; called by muse, varscan2
- ABCD1 | c.676T>G p.S226A | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV99497102; called by muse, varscan2
- ABCD2 | c.1968T>G p.I656M | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV100429060; called by muse, mutect2, varscan2
- ABCD3 | c.1200T>G p.D400E | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as COSV100931323; called by muse, mutect2, varscan2
- ABCG2 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.694); catalogued as COSV99418232; called by muse, mutect2, varscan2
- ABLIM1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs867453626, COSV99521151; called by muse, mutect2, varscan2
- AC011479.1 | c.447T>G p.I149M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0); catalogued as COSV100007754; called by muse, mutect2
- AC126283.2 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769721080, CM086400, CM136036, COSV101143955, COSV67097792; called by muse, mutect2, varscan2
- AC131160.1 | c.676A>G p.M226V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100225979; called by muse, mutect2
- ACACB | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100622085; called by muse, mutect2, varscan2
- ACADL | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs146706554; called by muse, mutect2, varscan2
- ACADSB | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs138063747; called by muse, mutect2, varscan2
- ACE | c.1626A>C p.E542D | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as COSV99326109; called by muse, mutect2, varscan2
- ACKR3 | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as COSV99799238; called by muse, mutect2, varscan2
- ACMSD | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99298675; called by muse, mutect2, varscan2
- ACO1 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100007481; called by muse, mutect2, varscan2
- ACP4 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141753566, COSV99567672; called by muse, mutect2, varscan2
- ACSBG1 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99356883; called by muse, varscan2
- ACSL1 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs372039837; called by mutect2, varscan2
- ACSL3 | c.366A>C p.K122N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62481998; called by muse, mutect2, varscan2
- ACSM3 | c.1720A>C p.K574Q | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.129); catalogued as COSV99184007; called by muse, mutect2, varscan2
- ACSS2 | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99489456; called by muse, mutect2, varscan2
- ACTN1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs200613938; called by muse, mutect2, varscan2
- ACTN2 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747674727, COSV100856439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM12 | c.1519T>C p.Y507H | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100899851; called by muse, varscan2
- ADAM22 | c.2441G>T p.R814M | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55972647; called by muse, mutect2, varscan2
- ADAM23 | c.247T>G p.L83V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100006212; called by muse, mutect2, varscan2
- ADAM28 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs143371817, COSV56098345; called by muse, mutect2, varscan2
- ADAM29 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 26/145 reads (18%) | catalogued as COSV100821845, COSV100822274; called by muse, mutect2, varscan2
- ADAM30 | c.1566C>A p.C522* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV101023724; called by muse, mutect2, varscan2
- ADAM7 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 65/204 reads (32%) | catalogued as rs1292901192, COSV51539710, COSV99442676; called by muse, mutect2, varscan2
- ADAM7 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 70/186 reads (38%) | catalogued as rs779521824, COSV99442678; called by muse, mutect2, varscan2
- ADAMTS12 | c.2520C>A p.C840* | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | catalogued as rs762596707, COSV100710024, COSV61281535; called by muse, mutect2, varscan2
- ADAMTS13 | c.2930G>C p.C977S | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM129654, COSV100746894; called by muse, mutect2, varscan2
- ADAMTS16 | c.1531T>G p.L511V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV99939496; called by muse, mutect2, varscan2
- ADAMTS16 | c.2059G>T p.G687* | Nonsense Mutation (SNP) | VAF 57/142 reads (40%) | catalogued as COSV56990019, COSV57010248; called by muse, mutect2, varscan2
- ADAMTS20 | c.2163G>T p.K721N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs551169111, COSV101238630; called by muse, mutect2, varscan2
- ADAMTS5 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs768917351, COSV53181660; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2356G>T p.D786Y | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV101001021; called by muse, mutect2, varscan2
- ADCK2 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs745347858, COSV99301295; called by muse, mutect2, varscan2
- ADCY10 | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100896445; called by muse, mutect2, varscan2
- ADCY4 | c.2033C>A p.A678D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100156002; called by muse, mutect2, varscan2
- ADD1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53273942; called by muse, mutect2, varscan2
- ADD3 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769868651, COSV53321355; called by muse, mutect2, varscan2
- ADGRB3 | c.1604A>C p.N535T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.984); catalogued as COSV100999401; called by muse, mutect2, varscan2
- ADGRB3 | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs747907463, COSV101000565, COSV65385017; called by muse, mutect2, varscan2
- ADGRB3 | c.3659C>A p.S1220Y | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53252123; called by muse, mutect2, varscan2
- ADGRE1 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99164976; called by muse, mutect2
- ADGRF5 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs199576297, COSV51930052; called by muse, mutect2, varscan2
- ADGRG4 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV99793987; called by muse, mutect2, varscan2
- ADGRG4 | c.6821C>T p.S2274L | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1272460149, COSV54956046; called by muse, mutect2, varscan2
- ADGRG4 | c.9158C>T p.S3053F | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs773552299, COSV99793988, COSV99795778; called by muse, mutect2, varscan2
- ADGRG6 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV99745331; called by muse, mutect2, varscan2
- ADGRG6 | c.2398C>A p.H800N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99745336; called by muse, mutect2, varscan2
- ADGRL2 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as COSV54650261; called by muse, mutect2, varscan2
- ADGRL3 | c.3495T>G p.I1165M (on ENST00000506720 / NM_001322402.2; = p.I1097M on NM_015236.6) | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV101546713; called by muse, mutect2, varscan2
- ADH4 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as COSV99643937, COSV99643982; called by muse, mutect2, varscan2
- ADIPOQ | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100292027; called by muse, mutect2, varscan2
- ADNP | c.1823C>A p.S608* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100823598; called by muse, mutect2, varscan2
- ADNP2 | c.3192G>T p.K1064N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV51538442; called by muse, mutect2, varscan2
- ADRA1B | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370209486, COSV60701675; called by muse, mutect2, varscan2
- ADRB2 | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100019040; called by muse, mutect2, varscan2
- AFF1 | c.2947G>A p.D983N | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV100320096; called by muse, mutect2, varscan2
- AGBL2 | c.2296A>C p.K766Q | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100100973, COSV54089813; called by muse, mutect2, varscan2
- AGBL2 | c.1416G>T p.M472I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100100985; called by muse, mutect2, varscan2
- AGL | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV99648143; called by muse, mutect2, varscan2
- AGL | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as rs776599112, CM140956, COSV54048187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGTR2 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs782664096, COSV100903516; called by muse, mutect2, varscan2
- AHCTF1 | c.5819A>C p.K1940T (on ENST00000366508; = p.K1914T on NM_015446.5) | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100402906; called by muse, mutect2
- AHCTF1 | c.178G>T p.E60* (on ENST00000366508; = p.E34* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as COSV58249512; called by muse, mutect2, varscan2
- AHNAK | c.16938A>C p.Q5646H | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV99945025; called by muse, mutect2, varscan2
- AHNAK | c.14921A>C p.K4974T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99945028; called by muse, mutect2, varscan2
- AHNAK | c.4169T>C p.F1390S | Missense Mutation (SNP) | VAF 19/305 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99945032; called by muse, mutect2
- AHNAK | c.3896T>G p.L1299R | Missense Mutation (SNP) | VAF 107/299 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99945035; called by muse, mutect2, varscan2
- AHNAK2 | c.17012G>T p.R5671I | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.51); catalogued as COSV100314809; called by muse, mutect2, varscan2
- AHNAK2 | c.16281A>C p.E5427D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100314813; called by muse, mutect2, varscan2
- AHRR | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as rs751244139, COSV100326378; called by muse, mutect2, varscan2
- AHSA1 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99375773; called by muse, mutect2, varscan2
- AIMP1 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs143219988; called by muse, mutect2, varscan2
- AKAP12 | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1263267238, COSV99482131; called by muse, mutect2, varscan2
- AKAP14 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 49/143 reads (34%) | catalogued as COSV100538191, COSV57631358; called by muse, mutect2, varscan2
- AKAP14 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100538192; called by muse, mutect2, varscan2
- AKAP3 | c.2307G>T p.Q769H | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV99961647; called by muse, mutect2, varscan2
- AKAP4 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.936); catalogued as COSV100654102, COSV62075413; called by muse, mutect2, varscan2
- AKAP4 | c.1131G>T p.E377D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100654103, COSV62074891; called by muse, mutect2, varscan2
- AKAP6 | c.2377C>A p.Q793K | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); catalogued as COSV99797179; called by muse, mutect2, varscan2
- AKAP6 | c.2728A>G p.K910E | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.757); catalogued as COSV99797181; called by muse, mutect2, varscan2
- AKAP6 | c.2988G>T p.Q996H | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.818); catalogued as COSV55210062, COSV99797183; called by muse, mutect2, varscan2
- AKAP6 | c.6341C>A p.S2114Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55236119, COSV99797186; called by muse, mutect2, varscan2
- AKAP7 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV53834415, COSV99541199; called by muse, mutect2, varscan2
- AKIRIN1 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100881969; called by muse, mutect2, varscan2
- AKR1C4 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781989291, COSV99578428; called by muse, mutect2, varscan2
- AKR1D1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs779758762, COSV54339065; called by muse, mutect2, varscan2
- AL136295.1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 72/247 reads (29%) | catalogued as COSV99841546; called by muse, mutect2, varscan2
- AL645922.1 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 45/119 reads (38%) | catalogued as COSV100190444; called by muse, mutect2, varscan2
- ALAS1 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100050135, COSV100050357; called by muse, mutect2
- ALCAM | c.842T>G p.F281C | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100063998; called by muse, mutect2, varscan2
- ALDH1A2 | c.1157A>C p.E386A | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.948); catalogued as COSV99990115; called by muse, mutect2, varscan2
- ALDH1L2 | c.1557G>T p.E519D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV99310525; called by muse, mutect2
- ALDH6A1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs759603010, COSV100620760; called by muse, mutect2, varscan2
- ALDOA | c.436C>T p.R146C (on ENST00000642816 / NM_001243177.4; = p.R92C on NM_184041.5) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs776187312, COSV100581838; called by muse, varscan2
- ALG10B | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 84/278 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100439747; called by muse, mutect2, varscan2
- ALG13 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 46/150 reads (31%) | catalogued as COSV52641937; called by muse, mutect2, varscan2
- ALG2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189167741; called by muse, mutect2, varscan2
- ALG9 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV101211829; called by muse, mutect2, varscan2
- ALKBH2 | c.782A>C p.K261T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as COSV99980016; called by muse, mutect2, varscan2
- ALKBH3 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 36/114 reads (32%) | catalogued as COSV100236001; called by muse, mutect2, varscan2
- ALMS1 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV100040675; called by muse, mutect2, varscan2
- ALMS1 | c.5909T>C p.V1970A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs765405386, COSV100040679; called by muse, mutect2, varscan2
- ALOX12B | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV100046472, COSV59873017; called by muse, mutect2, varscan2
- ALOXE3 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as COSV100559575; called by muse, mutect2, varscan2
- ALPK1 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99452711; called by muse, mutect2, varscan2
- ALPK2 | c.3211G>T p.E1071* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as rs144840598; called by muse, mutect2, varscan2
- AMBN | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59825360; called by muse, mutect2, varscan2
- AMER2 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV100766073; called by muse, mutect2
- AMER3 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs541254437, COSV100365820; called by muse, mutect2, varscan2
- AMY2B | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 139/397 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100796135; called by muse, varscan2
- AMY2B | c.865A>G p.M289V | Missense Mutation (SNP) | VAF 119/362 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV100796136; called by muse, mutect2, varscan2
- ANGPT2 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100290422; called by muse, varscan2
- ANGPTL5 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.172); catalogued as rs756417169, COSV100527554, COSV57533607; called by muse, varscan2
- ANGPTL5 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV100527555; called by muse, varscan2
- ANK1 | c.3442C>T p.R1148W | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs148589308; called by muse, mutect2, varscan2
- ANK2 | c.7564C>A p.L2522I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV52147287; called by muse, mutect2, varscan2
- ANK2 | c.9587C>T p.S3196L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); catalogued as rs144719173, COSV52190287; called by muse, mutect2, varscan2
- ANKAR | c.3128G>T p.R1043I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs372369306, COSV55618459; called by muse, mutect2, varscan2
- ANKFY1 | c.2903T>C p.V968A (on ENST00000341657 / NM_001330063.2; = p.V969A on NM_016376.5) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100492101; called by muse, mutect2, varscan2
- ANKRD12 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100040483; called by muse, mutect2, varscan2
- ANKRD12 | c.2138T>C p.M713T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs374786688; called by muse, mutect2, varscan2
- ANKRD12 | c.4607A>G p.D1536G | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV100040486; called by muse, mutect2, varscan2
- ANKRD24 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs771940507, COSV99516717; called by muse, varscan2
- ANKRD26 | c.4684G>T p.E1562* | Nonsense Mutation (SNP) | VAF 40/123 reads (33%) | catalogued as COSV101062805; called by muse, mutect2, varscan2
- ANKRD28 | c.1848G>T p.L616F | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.025); catalogued as COSV101080146; called by muse, mutect2, varscan2
- ANKRD30A | c.1472C>A p.S491Y (on ENST00000611781; = p.S435Y on NM_052997.2) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.645); catalogued as COSV100652538; called by muse, mutect2, varscan2
- ANKRD30A | c.2938G>T p.D980Y (on ENST00000611781; = p.D924Y on NM_052997.2) | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100652539; called by muse, mutect2, varscan2
- ANKRD30A | c.3375C>A p.Y1125* (on ENST00000611781; = p.Y1069* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100652542; called by muse, mutect2, varscan2
- ANKRD30A | c.3467C>A p.S1156* (on ENST00000611781; = p.S1100* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV64614463, COSV64624230; called by muse, mutect2, varscan2
- ANKRD30A | c.3826G>T p.E1276* (on ENST00000611781; = p.E1220* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 47/157 reads (30%) | catalogued as COSV100652545, COSV100654461; called by muse, mutect2, varscan2
- ANKRD36B | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 165/446 reads (37%) | catalogued as COSV99307720; called by muse, mutect2, varscan2
- ANKRD6 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as rs373783227; called by muse, mutect2, varscan2
- ANO4 | c.2148G>T p.M716I (on ENST00000392977 / NM_001286615.2; = p.M681I on NM_178826.4) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV100151246; called by muse, mutect2, varscan2
- ANXA5 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs759791586, COSV99634063; called by muse, mutect2, varscan2
- ANXA7 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.172); catalogued as COSV100873375; called by muse, mutect2, varscan2
- AOC1 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs560992275, COSV62867097; called by muse, mutect2
- AP4M1 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs770777535, COSV57997606; called by muse, mutect2, varscan2
- APAF1 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777800292, COSV100141625; called by muse, mutect2, varscan2
- APAF1 | c.1628A>G p.N543S (on ENST00000551964 / NM_181861.2; = p.N532S on NM_001160.3) | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100452187; called by muse, mutect2, varscan2
- APAF1 | c.3436G>T p.D1146Y (on ENST00000551964 / NM_181861.2; = p.D1092Y on NM_001160.3) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100452193; called by muse, mutect2, varscan2
- APEH | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as rs577640330, COSV56517850; called by muse, mutect2, varscan2
- APH1A | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.142); catalogued as rs368536742, COSV52530067; called by muse, mutect2, varscan2
- APIP | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs200417952, COSV53506760; called by muse, mutect2, varscan2
- APOBEC3F | c.63T>G p.F21L | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100415066; called by muse, mutect2, varscan2
- APOH | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1341548729, COSV99235414; called by muse, mutect2, varscan2
- APOH | c.475T>A p.S159T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.03); catalogued as COSV99235418; called by muse, mutect2, varscan2
- APPL1 | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 52/128 reads (41%) | catalogued as rs1429184808, COSV55699870, COSV99897215; called by muse, mutect2, varscan2
- AQP3 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.57); PolyPhen probably damaging (1); catalogued as rs777633399, COSV99955439; called by muse, mutect2, varscan2
- AQP3 | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV53049170, COSV99955443; called by muse, mutect2, varscan2
- AQR | c.4066A>C p.K1356Q | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99332912; called by muse, mutect2, varscan2
- ARAF | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV51692445; called by muse, mutect2, varscan2
- ARAP2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV100393921; called by muse, mutect2, varscan2
- ARHGAP11A | c.932G>T p.R311I | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs372419991; called by muse, mutect2, varscan2
- ARHGAP22 | c.159C>A p.N53K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV99984118; called by muse, varscan2
- ARHGAP28 | c.2017C>A p.Q673K (on ENST00000383472 / NM_001366230.1; = p.Q514K on NM_001010000.3) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV99148097; called by muse, mutect2, varscan2
- ARHGAP32 | c.575T>G p.F192C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100086458; called by muse, mutect2, varscan2
- ARHGAP35 | c.1589T>C p.F530S | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV101350575; called by muse, mutect2, varscan2
- ARHGAP39 | c.1895T>C p.L632P | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99430040; called by muse, mutect2, varscan2
- ARHGAP4 | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV63133250, COSV63134924; called by muse, mutect2
- ARHGEF10 | c.863C>T p.S288L (on ENST00000398564; = p.S263L on NM_014629.4) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs775934719, COSV100033327; called by muse, mutect2, varscan2
- ARHGEF28 | c.3687T>G p.I1229M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99707822; called by muse, mutect2, varscan2
- ARHGEF38 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99485935; called by muse, mutect2
- ARHGEF40 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1291849058, COSV53879837; called by muse, mutect2, varscan2
- ARHGEF6 | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as rs952314313, COSV51691658; called by muse, mutect2, varscan2
- ARHGEF6 | c.2017C>A p.Q673K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV99166313; called by muse, mutect2, varscan2
- ARHGEF7 | c.638T>C p.V213A (on ENST00000375741 / NM_001113511.2; = p.V35A on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99520618; called by muse, mutect2, varscan2
- ARHGEF9 | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99491181; called by muse, mutect2, varscan2
- ARID1B | c.4900C>A p.L1634I | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51664236; called by muse, mutect2
- ARID2 | c.3682T>C p.S1228P | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV100535115; called by muse, mutect2, varscan2
- ARID4B | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 42/129 reads (33%) | catalogued as COSV104384509, COSV99934716; called by muse, mutect2, varscan2
- ARID5B | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV54418646, COSV99688718; called by muse, mutect2, varscan2
- ARID5B | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs550591609, COSV99688722; called by muse, mutect2, varscan2
- ARL6IP4 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV99758018; called by muse, mutect2, varscan2
- ARL8B | c.205-1G>T p.X69_splice | Splice Site (SNP) | VAF 37/153 reads (24%) | catalogued as COSV99848409; called by muse, mutect2, varscan2
- ARMC1 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.339); catalogued as COSV52534752; called by muse, mutect2, varscan2
- ARMC4 | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV100536020; called by muse, mutect2, varscan2
- ARMCX2 | c.1538T>G p.F513C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100167972; called by muse, mutect2, varscan2
- ARMCX3 | c.280G>C p.A94P | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100362149; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV100771708; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV100771710; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100771712; called by muse, mutect2, varscan2
- ARPIN | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100673410; called by muse, mutect2, varscan2
- ARPP21 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV51794552, COSV51810314; called by muse, mutect2, varscan2
- ARR3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV100330764; called by muse, mutect2, varscan2
- ARSF | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs751497726, COSV63838954; called by muse, mutect2, varscan2
- ARSK | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); catalogued as COSV101187481; called by muse, mutect2, varscan2
- ART4 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV99966755; called by muse, mutect2, varscan2
- ASAP2 | c.644A>G p.D215G | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99855531; called by muse, mutect2, varscan2
- ASB17 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs1389873604, COSV99407755, COSV99407871, COSV99407958; called by muse, mutect2, varscan2
- ASB7 | c.944T>C p.F315S | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated, low confidence (0.64); PolyPhen possibly damaging (0.665); catalogued as COSV100234894, COSV60417325; called by muse, mutect2, varscan2
- ASB9 | c.591A>C p.K197N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV100995354; called by muse, mutect2, varscan2
- ASCC3 | c.3397C>A p.L1133I | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV100224964; called by muse, mutect2, varscan2
- ASL | c.180G>T p.M60I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as COSV100508760; called by muse, mutect2, varscan2
- ASNS | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV99445765; called by muse, mutect2, varscan2
- ASPM | c.10274C>A p.S3425Y | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV54127420, COSV54137455, COSV99659149; called by muse, mutect2, varscan2
- ASPM | c.6682G>T p.E2228* | Nonsense Mutation (SNP) | VAF 79/248 reads (32%) | catalogued as COSV99659152; called by muse, mutect2, varscan2
- ASPM | c.4396A>C p.N1466H | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV99659154; called by muse, mutect2, varscan2
- ASTE1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as rs200737048, COSV53910585; called by muse, mutect2, varscan2
- ASTN1 | c.392T>G p.L131R | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.447); catalogued as COSV99920014; called by muse, mutect2, varscan2
- ASXL3 | c.3427G>T p.E1143* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV52461420, COSV99322712; called by muse, mutect2, varscan2
- ASZ1 | c.1188G>T p.Q396H | Missense Mutation (SNP) | VAF 71/97 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as COSV99497639; called by muse, mutect2, varscan2
- ATAD2 | c.3980T>C p.V1327A | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99783841; called by muse, mutect2, varscan2
- ATG16L1 | c.1447C>T p.R483* (on ENST00000392017 / NM_030803.7; = p.R464* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 37/111 reads (33%) | catalogued as COSV100731192; called by muse, mutect2, varscan2
- ATG2B | c.5300C>A p.S1767Y | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99951864; called by muse, mutect2, varscan2
- ATG2B | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 60/136 reads (44%) | catalogued as COSV100737603; called by muse, mutect2, varscan2
- ATG4A | c.122-1G>A p.X41_splice | Splice Site (SNP) | VAF 29/115 reads (25%) | catalogued as COSV100619488; called by muse, mutect2, varscan2
- ATG4B | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV100728546; called by muse, mutect2, varscan2
- ATG9B | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.326); catalogued as COSV99870978; called by muse, mutect2, varscan2
- ATM | c.1795C>A p.L599I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.019); catalogued as COSV99586573; called by muse, mutect2, varscan2
- ATM | c.7223C>T p.S2408L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs730881315, COSV53738904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10D | c.2617G>T p.E873* | Nonsense Mutation (SNP) | VAF 48/141 reads (34%) | catalogued as rs1318759213, COSV99904918, COSV99905362; called by muse, mutect2, varscan2
- ATP11A | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1443017095, COSV52108983; called by muse, mutect2, varscan2
- ATP11C | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100557089; called by muse, mutect2, varscan2
- ATP1A1 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55190351, COSV55190747; called by muse, mutect2, varscan2
- ATP1A3 | c.1288C>T p.L430F (on ENST00000545399 / NM_001256214.2; = p.L417F on NM_152296.5) | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV57491398; called by muse, mutect2, varscan2
- ATP1A4 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 50/155 reads (32%) | catalogued as rs565184841, COSV100927423, COSV63625976; called by muse, mutect2
- ATP5F1C | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 47/157 reads (30%) | catalogued as rs1436478284, COSV59620786; called by muse, mutect2, varscan2
- ATP6AP2 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs769027148, COSV101011411; called by muse, varscan2
- ATP6V0A2 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 63/172 reads (37%) | catalogued as COSV100376747; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.974); catalogued as COSV100022402; called by muse, mutect2, varscan2
- ATP6V0A4 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 34/109 reads (31%) | catalogued as COSV100022403; called by muse, mutect2, varscan2
- ATP6V0D2 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99571127; called by muse, mutect2, varscan2
- ATP8B1 | c.2762C>T p.S921L | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs367575213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B1 | c.1403A>C p.K468T | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99376641; called by muse, mutect2, varscan2
- ATP8B4 | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99462686; called by muse, mutect2, varscan2
- ATR | c.3419G>A p.S1140N | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as COSV100637520; called by muse, mutect2, varscan2
- ATRN | c.1463G>T p.S488I | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV99496315; called by muse, mutect2, varscan2
- ATRN | c.2566T>G p.W856G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99496317; called by muse, mutect2, varscan2
- ATXN10 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs1042452273, COSV53298989, COSV99426550; called by muse, mutect2, varscan2
- AURKA | c.154A>C p.N52H | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397339267, COSV100452696; called by muse, mutect2, varscan2
- AVL9 | c.1745C>A p.S582Y | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100594457; called by muse, mutect2, varscan2
- AZI2 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV99843341; called by muse, mutect2, varscan2
- AZIN2 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99612790; called by muse, mutect2, varscan2
- B2M | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 57/168 reads (34%) | catalogued as COSV62563605; called by muse, mutect2, varscan2
- BAAT | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV52287479; called by muse, mutect2, varscan2
- BABAM2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558639513, COSV59622455, COSV59628195; called by muse, mutect2, varscan2
- BACH1 | c.235-1G>T p.X79_splice | Splice Site (SNP) | VAF 31/118 reads (26%) | catalogued as COSV99727783; called by muse, mutect2, varscan2
- BAG6 | c.1768C>A p.L590I (on ENST00000676571; = p.L543I on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99276151; called by muse, mutect2, varscan2
- BANK1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100535571, COSV59850236; called by muse, mutect2, varscan2
- BARHL2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs751500391, COSV100966005; called by muse, mutect2, varscan2
- BAZ2B | c.4834T>G p.L1612V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV100600217; called by muse, mutect2, varscan2
- BAZ2B | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV100600219; called by muse, mutect2, varscan2
- BBX | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100360708; called by muse, mutect2, varscan2
- BCAP31 | c.153C>A p.F51L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.229); catalogued as COSV99497097; called by muse, mutect2, varscan2
- BCAR1 | c.2295C>A p.F765L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); catalogued as COSV99365716; called by muse, mutect2, varscan2
- BCHE | c.1147A>C p.K383Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100011868; called by muse, mutect2, varscan2
- BCL10 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65353663, COSV65353778; called by muse, mutect2, varscan2
- BCL6B | c.1143G>T p.E381D | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV99546319; called by muse, mutect2, varscan2
- BCLAF1 | c.2104A>C p.K702Q | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99219203; called by muse, mutect2, varscan2
- BCLAF1 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100786356; called by muse, varscan2
- BCO2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752219938, COSV63063308; called by muse, mutect2, varscan2
- BEND2 | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV101191656; called by muse, mutect2, varscan2
- BEST3 | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as COSV100437451; called by muse, mutect2, varscan2
- BEX5 | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100374969; called by muse, varscan2
- BFSP1 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs199533439, COSV64901836; called by muse, mutect2, varscan2
- BGN | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1240227405, COSV59035878, COSV59038133; called by muse, mutect2, varscan2
- BGN | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as COSV100525175, COSV59035987; called by muse, mutect2, varscan2
- BIN2 | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99909019; called by muse, mutect2, varscan2
- BIRC2 | c.1435C>A p.L479M | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs1371246072, COSV99926446; called by muse, mutect2, varscan2
- BIRC3 | c.1301G>T p.R434I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV99679560; called by muse, mutect2, varscan2
- BIRC6 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101427711; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99958434; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1271G>T p.R424I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV57279584; called by muse, mutect2, varscan2
- BMP15 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs781806618, COSV53141164; called by muse, mutect2
- BMP3 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1435451372, COSV51081644; called by muse, mutect2, varscan2
- BMPER | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs747828408, COSV51816095, COSV99778509; called by muse, mutect2, varscan2
- BMPR1A | c.1496T>G p.L499R | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100923204; called by muse, mutect2, varscan2
- BRAF | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.074); catalogued as rs779101864, COSV99947768; called by muse, mutect2, varscan2
- BRAP | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.715); catalogued as rs145317226; called by muse, mutect2, varscan2
- BRAP | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs377591727, COSV59535424; called by muse, mutect2, varscan2
- BRCA1 | c.4328G>A p.R1443Q | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs4986849; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- BRCA2 | c.82A>C p.S28R | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101203785; called by muse, mutect2, varscan2
- BRCA2 | c.3337G>T p.E1113* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV66453314; called by muse, mutect2, varscan2
- BRCA2 | c.8820A>C p.K2940N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as CD087881, COSV101203787; called by muse, varscan2
- BRDT | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100746011; called by muse, mutect2, varscan2
- BRINP3 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV66534364; called by muse, mutect2, varscan2
- BRMS1L | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV99396424; called by muse, mutect2, varscan2
- BRWD1 | c.4297C>T p.R1433* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as rs752494269, COSV60892572; called by muse, mutect2, varscan2
- BRWD1 | c.3520G>T p.D1174Y | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100312527; called by muse, mutect2, varscan2
- BRWD1 | c.530A>C p.K177T | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100312531; called by muse, mutect2, varscan2
- BRWD3 | c.5141G>T p.R1714I | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.202); catalogued as COSV100955521; called by muse, mutect2, varscan2
- BRWD3 | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100955522; called by muse, mutect2, varscan2
- BSN | c.4015G>A p.D1339N | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs758036810, COSV99606824; called by muse, varscan2
- BST1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99399708; called by muse, mutect2, varscan2
- BTAF1 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs775680358, COSV99794653; called by muse, mutect2, varscan2
- BTBD11 | c.2892G>T p.E964D (on ENST00000280758 / NM_001018072.2; = p.E501D on NM_001017523.2) | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV99774385; called by muse, mutect2, varscan2
- BTN2A1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 43/96 reads (45%) | catalogued as COSV100438305; called by muse, mutect2, varscan2
- BTN3A2 | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV100709522; called by muse, mutect2, varscan2
- BUB1 | c.1414A>G p.M472V | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100240716; called by muse, mutect2, varscan2
- BZW1 | c.699T>G p.F233L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100729807; called by muse, mutect2, varscan2
- C10orf120 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1431253930, COSV61491778, COSV61492642; called by muse, mutect2, varscan2
- C10orf90 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs752025882, COSV52949458; called by muse, mutect2, varscan2
- C11orf65 | c.883A>C p.N295H | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.912); catalogued as rs933332341, COSV101262672; called by muse, mutect2, varscan2
- C12orf56 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV100398895; called by muse, mutect2, varscan2
- C16orf78 | c.532T>G p.S178A | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100147477; called by muse, varscan2
- C16orf78 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100147479; called by muse, varscan2
- C17orf80 | c.1126C>A p.L376I | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99277686; called by muse, mutect2, varscan2
- C1R | c.1973C>A p.S658Y (on ENST00000536053 / NM_001354346.2; = p.S644Y on NM_001733.7) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.396); catalogued as COSV101605600, COSV101605625; called by muse, mutect2, varscan2
- C20orf194 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99329984; called by muse, mutect2, varscan2
- C22orf23 | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.273); catalogued as COSV99316904; called by muse, mutect2, varscan2
- C2orf16 | c.3629G>A p.S1210N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs545742634, COSV100820571; called by muse, mutect2, varscan2
- C2orf78 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV101280874; called by muse, mutect2, varscan2
- C3orf62 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as rs1238697922, COSV57986647; called by muse, mutect2, varscan2
- C4B | c.3507A>C p.E1169D | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV101312116; called by muse, mutect2, varscan2
- C4BPB | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as rs1346400975, COSV99699796; called by muse, mutect2, varscan2
- C5 | c.2290G>T p.E764* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99796865; called by muse, mutect2, varscan2
- C5orf24 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100574407; called by muse, mutect2, varscan2
- C5orf46 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs772440075, COSV59153812; called by muse, mutect2, varscan2
- C6 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 31/89 reads (35%) | catalogued as COSV99666105; called by muse, mutect2, varscan2
- C7 | c.869G>T p.S290I | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100495196; called by muse, mutect2, varscan2
- C7 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs772422101, COSV57470105; called by muse, mutect2, varscan2
- C9orf116 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100876596; called by muse, mutect2, varscan2
- CA10 | c.83T>A p.I28N | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV99560790, COSV99565340; called by muse, mutect2, varscan2
- CABLES1 | c.1475C>T p.S492L (on ENST00000256925 / NM_001100619.2; = p.S227L on NM_138375.2) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs756944411, COSV99908122; called by muse, mutect2, varscan2
- CACHD1 | c.2493T>G p.D831E | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.846); catalogued as COSV99261114; called by muse, mutect2, varscan2
- CACNA1E | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100701096; called by muse, mutect2, varscan2
- CACNA1E | c.4947C>A p.F1649L | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100701098, COSV100704864; called by muse, mutect2, varscan2
- CACNA1S | c.5264A>C p.K1755T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV100754486; called by muse, mutect2, varscan2
- CACNA1S | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100754487; called by muse, mutect2, varscan2
- CACNG3 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV50077179; called by muse, mutect2, varscan2
- CADPS2 | c.3805G>T p.V1269L | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100460096; called by muse, mutect2, varscan2
- CADPS2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | catalogued as COSV57368748; called by muse, mutect2, varscan2
- CALCOCO1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs376685260, COSV50425439; called by muse, mutect2, varscan2
- CALCOCO2 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99363583; called by muse, mutect2, varscan2
- CALCR | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100810242; called by muse, mutect2, varscan2
- CAMK4 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV56677647; called by muse, mutect2, varscan2
- CAMKK1 | c.879C>A p.D293E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99339853; called by muse, mutect2, varscan2
- CAMSAP2 | c.2167A>G p.T723A (on ENST00000236925 / NM_001297707.2; = p.T712A on NM_203459.3) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99372669; called by muse, mutect2, varscan2
- CAMSAP3 | c.150G>A p.E50= | Splice Region (SNP) | VAF 48/145 reads (33%) | catalogued as rs375385665; called by muse, mutect2, varscan2
- CAPN6 | c.1769A>G p.D590G | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136576; called by muse, mutect2, varscan2
- CAPN6 | c.1705T>G p.F569V | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100136578; called by muse, mutect2, varscan2
- CAPRIN2 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 59/170 reads (35%) | catalogued as COSV51831146, COSV51835000; called by muse, mutect2, varscan2
- CARF | c.647T>G p.I216S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100247405; called by muse, mutect2, varscan2
- CARMIL2 | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV100575885; called by muse, mutect2, varscan2
- CARMIL3 | c.3048C>A p.F1016L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100549010, COSV57728263; called by muse, mutect2, varscan2
- CASC3 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99229389; called by muse, mutect2, varscan2
- CASD1 | c.1199C>A p.S400* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV51970624, COSV99802072; called by muse, mutect2, varscan2
- CASKIN1 | c.1094C>A p.S365* | Nonsense Mutation (SNP) | VAF 56/162 reads (35%) | catalogued as COSV100623703; called by muse, mutect2, varscan2
- CASP3 | c.322C>A p.H108N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100394885; called by muse, mutect2
- CASP8 | c.538G>T p.E180* (on ENST00000432109 / NM_033355.3; = p.E212* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as COSV51861924; called by muse, mutect2, varscan2
- CASP9 | c.417C>T p.V139= | Splice Region (SNP) | VAF 57/232 reads (25%) | catalogued as rs141693490; called by muse, mutect2, varscan2
- CATSPER2 | c.1279A>C p.K427Q (on ENST00000321596 / NM_001282309.3; = p.K429Q on NM_172095.4) | Missense Mutation (SNP) | VAF 126/342 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.108); catalogued as COSV100390455; called by muse, varscan2
- CATSPER3 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs143499103; called by muse, mutect2, varscan2
- CATSPERE | c.2343T>A p.N781K | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100834830; called by muse, mutect2, varscan2
- CBLL1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.162); catalogued as COSV99755333; called by muse, mutect2, varscan2
- CBY2 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs1048522766, COSV60118086; called by muse, mutect2
- CCDC122 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99865760; called by muse, mutect2, varscan2
- CCDC125 | c.1502G>T p.R501I | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs1185332263, COSV67287874; called by muse, mutect2, varscan2
- CCDC126 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100277739; called by muse, mutect2, varscan2
- CCDC141 | c.1725G>T p.E575D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99835921; called by muse, mutect2, varscan2
- CCDC144A | c.2723G>T p.R908I | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV100138207; called by muse, mutect2, varscan2
- CCDC144A | c.3158G>A p.R1053Q | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs199644397; called by muse, mutect2, varscan2
- CCDC149 | c.680T>G p.L227* | Nonsense Mutation (SNP) | VAF 34/92 reads (37%) | catalogued as COSV100164453; called by muse, mutect2, varscan2
- CCDC151 | c.228A>C p.K76N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV99371178; called by muse, mutect2, varscan2
- CCDC158 | c.2289G>A p.E763= | Splice Region (SNP) | VAF 29/103 reads (28%) | catalogued as COSV101187120; called by muse, mutect2, varscan2
- CCDC17 | c.1412C>A p.S471Y | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1252979603, COSV100601516; called by muse, mutect2, varscan2
- CCDC170 | c.167T>G p.F56C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV53340485; called by muse, mutect2, varscan2
- CCDC171 | c.2718G>T p.K906N | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV52633945, COSV99899566; called by muse, mutect2, varscan2
- CCDC171 | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1390853224, COSV99899573; called by muse, mutect2, varscan2
- CCDC173 | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV101352350; called by muse, mutect2, varscan2
- CCDC178 | c.2382G>T p.K794N (on ENST00000383096 / NM_001105528.3; = p.K756N on NM_198995.3) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100282725; called by muse, mutect2, varscan2
- CCDC18 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); catalogued as COSV100159087; called by muse, mutect2, varscan2
- CCDC18 | c.3850A>G p.I1284V (on ENST00000343253 / NM_001306076.1; = p.I1285V on NM_206886.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as COSV100159090; called by muse, mutect2, varscan2
- CCDC198 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53601250; called by muse, mutect2
- CCDC28B | c.302A>G p.D101G | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99356229; called by muse, mutect2, varscan2
- CCDC54 | c.784T>G p.F262V | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99660099; called by muse, mutect2, varscan2
- CCDC58 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52248237, COSV99360365; called by muse, mutect2, varscan2
- CCDC73 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 40/124 reads (32%) | catalogued as COSV100067072, COSV58797184; called by muse, mutect2, varscan2
- CCDC87 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV100039649; called by muse, mutect2, varscan2
- CCDC87 | c.1957T>C p.W653R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100039652; called by muse, mutect2, varscan2
- CCDC87 | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100039654; called by muse, mutect2, varscan2
- CCDC91 | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV100080917; called by muse, mutect2, varscan2
- CCDC93 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 38/120 reads (32%) | catalogued as COSV60121151; called by muse, mutect2, varscan2
- CCL3 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs773703371; called by muse, mutect2, varscan2
- CCNA1 | c.300G>T p.G100= | Splice Region (SNP) | VAF 36/108 reads (33%) | catalogued as COSV99714154; called by muse, mutect2, varscan2
- CCNB1 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs763731070, COSV99841163; called by muse, mutect2, varscan2
- CCNB1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs776088624, COSV99841166; called by muse, mutect2, varscan2
- CCNB3 | c.860A>C p.K287T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV99328252; called by muse, mutect2, varscan2
- CCNB3 | c.1738G>T p.V580L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV99328254; called by muse, mutect2, varscan2
- CCNJL | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as COSV99979083; called by muse, mutect2, varscan2
- CCNL1 | c.1483C>A p.H495N | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV99904337; called by muse, mutect2, varscan2
- CCNT1 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99980372; called by muse, mutect2, varscan2
- CCNT2 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 44/124 reads (35%) | catalogued as COSV51472643; called by muse, mutect2, varscan2
- CCPG1 | c.2071A>G p.I691V | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV99379863; called by muse, mutect2, varscan2
- CCPG1 | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs771072961, COSV99379864; called by muse, varscan2
- CCR3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as rs1043285757, COSV100656740, COSV62463212; called by muse, mutect2, varscan2
- CCR3 | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.608); catalogued as COSV100656214; called by muse, mutect2, varscan2
- CCR7 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV99878518; called by muse, mutect2, varscan2
- CCT2 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV100167464; called by muse, mutect2, varscan2
- CCT6A | c.798C>A p.F266L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV51905595, COSV99303152; called by muse, mutect2, varscan2
- CCT8L2 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 53/121 reads (44%) | catalogued as COSV100742493; called by muse, mutect2, varscan2
- CCZ1B | c.904T>A p.F302I | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV100367674; called by muse, mutect2, varscan2
- CD19 | c.1601A>G p.N534S (on ENST00000324662 / NM_001178098.2; = p.N533S on NM_001770.6) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100217973; called by muse, varscan2
- CD209 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 133/332 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.74); catalogued as COSV99213491; called by muse, mutect2, varscan2
- CD226 | c.875A>C p.D292A | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99710603; called by muse, mutect2, varscan2
- CD244 | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100458065; called by muse, mutect2, varscan2
- CD2AP | c.801A>C p.K267N | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV100830247; called by muse, mutect2, varscan2
- CD34 | c.89T>G p.F30C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100178055; called by muse, mutect2, varscan2
- CD53 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99602008; called by muse, mutect2, varscan2
- CDAN1 | c.1078T>G p.F360V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CM060011, COSV99141013, COSV99141390; called by muse, mutect2, varscan2
- CDC123 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99826593; called by muse, mutect2, varscan2
- CDC27 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50368255; called by muse, mutect2, varscan2
- CDC42 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100212468; called by muse, mutect2, varscan2
- CDC42BPA | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.107); catalogued as rs772380478, COSV62009001; called by muse, mutect2, varscan2
- CDC5L | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as COSV101014798; called by muse, mutect2, varscan2
- CDC5L | c.2320G>A p.V774I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV101014799; called by muse, mutect2, varscan2
- CDH18 | c.1386A>C p.E462D | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV99931073; called by muse, mutect2, varscan2
- CDH19 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV50979350, COSV50985804; called by muse, mutect2
- CDH23 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); catalogued as COSV54949600, COSV99818053; called by muse, mutect2, varscan2
- CDH9 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs138749280; called by muse, mutect2, varscan2
- CDHR2 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.009); catalogued as COSV99990817; called by muse, mutect2, varscan2
- CDK13 | c.2770G>T p.E924* | Nonsense Mutation (SNP) | VAF 22/142 reads (15%) | catalogued as COSV99474834; called by muse, mutect2, varscan2
- CDK5 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as COSV99876518; called by muse, mutect2, varscan2
- CDK5RAP2 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 62/256 reads (24%) | catalogued as COSV62577599; called by muse, mutect2, varscan2
- CDK7 | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.055); catalogued as COSV99841463; called by muse, mutect2, varscan2
- CDK8 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933264029, COSV67420475; called by muse, mutect2, varscan2
- CDKL1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99367129; called by muse, mutect2, varscan2
- CDKL2 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV56733877; called by muse, mutect2, varscan2
- CDKL5 | c.1147A>G p.T383A | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV101183953; called by muse, mutect2, varscan2
- CDRT1 | c.2042G>T p.R681I | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.766); catalogued as COSV63053063, COSV63054201; called by muse, mutect2, varscan2
- CDS2 | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV100986042; called by muse, mutect2, varscan2
- CEACAM18 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.018); catalogued as rs765961156, COSV101140056; called by muse, mutect2, varscan2
- CEACAM20 | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV100386740; called by muse, mutect2, varscan2
- CELF4 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100610817; called by muse, mutect2
- CENPH | c.239+1G>A p.X80_splice | Splice Site (SNP) | VAF 30/82 reads (37%) | catalogued as rs369923920; called by muse, mutect2, varscan2
- CENPI | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV54501683; called by muse, mutect2, varscan2
- CENPI | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV99514908, COSV99514930; called by muse, mutect2, varscan2
- CENPO | c.866G>T p.R289I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99567436; called by muse, mutect2, varscan2
- CEP112 | c.2522C>A p.A841D (on ENST00000392769 / NM_001353127.1; = p.A97D on NM_001037325.3) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.715); catalogued as COSV100438771; called by muse, mutect2, varscan2
- CEP126 | c.1522T>G p.F508V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.169); catalogued as COSV99680374; called by muse, mutect2, varscan2
- CEP128 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV99382647; called by muse, mutect2, varscan2
- CEP152 | c.4391T>C p.F1464S (on ENST00000380950 / NM_001194998.2; = p.F1408S on NM_014985.4) | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.209); catalogued as COSV100358348; called by muse, mutect2
- CEP170 | c.4348T>G p.W1450G | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100316142; called by muse, mutect2, varscan2
- CEP290 | c.1536G>T p.K512N | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs750163383, COSV100467453, COSV58355378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP350 | c.4873C>T p.R1625* | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | catalogued as rs1181129362, COSV62601953; called by muse, mutect2, varscan2
- CEP43 | c.217T>G p.L73V | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV100835518; called by muse, mutect2, varscan2
- CEP55 | c.1163G>T p.R388I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV101016761; called by muse, mutect2, varscan2
- CEP70 | c.1497G>T p.M499I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV99388673; called by muse, mutect2, varscan2
- CEP76 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV100042541; called by muse, mutect2, varscan2
- CEP97 | c.2534T>G p.V845G | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100511457; called by muse, mutect2, varscan2
- CERS6 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV59835217; called by muse, mutect2
- CERT1 | c.1838C>T p.A613V (on ENST00000405807 / NM_001130105.1; = p.A485V on NM_005713.3) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV99782650; called by muse, mutect2, varscan2
- CFAP206 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as rs755706034, COSV99738932; called by muse, mutect2, varscan2
- CFAP221 | c.1870A>C p.K624Q | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as COSV54657442, COSV99731694; called by muse, mutect2, varscan2
- CFAP251 | c.2065T>G p.F689V | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99995570; called by muse, mutect2, varscan2
- CFAP300 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as rs140641107; called by muse, mutect2, varscan2
- CFAP36 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 23/97 reads (24%) | catalogued as COSV59119168; called by muse, mutect2, varscan2
- CFAP43 | c.2045A>C p.Q682P | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV99530231; called by muse, mutect2, varscan2
- CFAP43 | c.963+1G>A p.X321_splice | Splice Site (SNP) | VAF 18/80 reads (23%) | catalogued as COSV99530235; called by muse, mutect2, varscan2
- CFAP45 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV63647976; called by muse, mutect2, varscan2
- CFAP47 | c.635G>T p.R212I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs941369539, COSV99934006, COSV99934652; called by muse, mutect2, varscan2
- CFAP52 | c.1615G>T p.E539* | Nonsense Mutation (SNP) | VAF 40/132 reads (30%) | catalogued as COSV53300250; called by muse, mutect2, varscan2
- CFAP53 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as COSV101274921; called by muse, mutect2, varscan2
- CFAP54 | c.7877C>A p.S2626Y | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100732834; called by muse, mutect2, varscan2
- CFAP57 | c.1712C>A p.A571D | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100993712; called by muse, mutect2, varscan2
- CFAP58 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV57211343, COSV57211825; called by muse, mutect2, varscan2
- CFAP58 | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100458644; called by muse, mutect2, varscan2
- CFAP58 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100458649; called by muse, mutect2, varscan2
- CFAP58 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100866015; called by muse, mutect2, varscan2
- CFAP65 | c.2264G>A p.W755* | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | catalogued as COSV100444340; called by muse, varscan2
- CFAP70 | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 68/226 reads (30%) | catalogued as COSV60284097; called by muse, mutect2, varscan2
- CFAP70 | c.1215A>C p.Q405H | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV100160005; called by muse, mutect2, varscan2
- CFAP91 | c.360-1G>T p.X120_splice | Splice Site (SNP) | VAF 54/145 reads (37%) | catalogued as COSV56343699, COSV99846736; called by muse, mutect2, varscan2
- CFAP92 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV99414466; called by muse, mutect2, varscan2
- CFDP1 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV99382352; called by muse, mutect2, varscan2
- CFHR1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57626879; called by muse, mutect2, varscan2
- CHAT | c.1712G>T p.R571I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100339456, COSV60328097; called by muse, mutect2, varscan2
- CHD2 | c.1169A>C p.K390T | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100560399; called by muse, mutect2, varscan2
- CHD2 | c.2530G>T p.E844* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as COSV101244487; called by muse, mutect2, varscan2
- CHD2 | c.4137+1G>T p.X1379_splice | Splice Site (SNP) | VAF 31/111 reads (28%) | catalogued as COSV101244489; called by muse, mutect2, varscan2
- CHD3 | c.2578A>C p.T860P | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100390445; called by muse, mutect2, varscan2
- CHD3 | c.5198C>T p.S1733L (on ENST00000330494 / NM_001005273.3; = p.S1699L on NM_005852.4) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1453924635, COSV57873038; called by muse, mutect2, varscan2
- CHD6 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497532; called by muse, mutect2, varscan2
- CHD7 | c.7444A>G p.M2482V | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as rs369402366; called by muse, mutect2, varscan2
- CHGA | c.258C>T p.G86= | Splice Region (SNP) | VAF 23/65 reads (35%) | catalogued as rs753415578, COSV53664934; called by muse, mutect2, varscan2
- CHIT1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as rs1347685066, COSV55147414; called by muse, mutect2, varscan2
- CHIT1 | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs1255210918, COSV99704937; called by muse, mutect2, varscan2
- CHL1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.096); catalogued as COSV99849603; called by muse, varscan2
- CHL1 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as COSV56586240; called by muse, varscan2
- CHM | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1386869495, COSV100752902; called by muse, mutect2, varscan2
- CHML | c.1487C>A p.S496Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV59367342; called by muse, mutect2, varscan2
- CHPT1 | c.649-1G>T p.X217_splice | Splice Site (SNP) | VAF 57/182 reads (31%) | catalogued as COSV99977550; called by muse, mutect2, varscan2
- CHRFAM7A | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV100241482; called by muse, mutect2, varscan2
- CHRM3 | c.1366C>A p.L456M | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.223); catalogued as COSV99697065; called by muse, varscan2
- CHSY3 | c.1630T>G p.L544V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.173); catalogued as rs1457325181, COSV100518178; called by muse, mutect2, varscan2
- CHUK | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 32/102 reads (31%) | catalogued as COSV100956913, COSV64918424; called by muse, mutect2, varscan2
- CHUK | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 37/102 reads (36%) | catalogued as COSV64917507, COSV64918255; called by muse, mutect2, varscan2
- CIT | c.3633A>C p.K1211N | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99947941; called by muse, mutect2, varscan2
- CKS1B | c.134A>C p.N45T | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.253); catalogued as COSV100460299; called by muse, mutect2
- CLASP2 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs754123905, COSV56288167; called by muse, mutect2
- CLBA1 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as COSV101120933; called by muse, mutect2, varscan2
- CLCA2 | c.2375T>G p.F792C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV100991260; called by muse, mutect2, varscan2
- CLCN3 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100641544; called by muse, mutect2, varscan2
- CLCN4 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101073568; called by muse, mutect2, varscan2
- CLCN4 | c.2209A>C p.I737L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.68); catalogued as COSV101073571; called by muse, mutect2, varscan2
- CLCN5 | c.929T>C p.F310S | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV100259685; called by muse, mutect2, varscan2
- CLCN6 | c.2042A>G p.Y681C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs1288842100, COSV100411423; called by muse, mutect2, varscan2
- CLCN7 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765444328, CM099579, COSV51968811; called by muse, mutect2
- CLDN16 | c.574+1G>T p.X192_splice | Splice Site (SNP) | VAF 33/89 reads (37%) | catalogued as CS084731, COSV99289877; called by muse, mutect2, varscan2
- CLEC17A | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated, low confidence (0.77); PolyPhen probably damaging (0.952); catalogued as rs762963063, COSV60427169; called by muse, mutect2, varscan2
- CLEC18C | c.1214T>G p.F405C | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100032001; called by muse, varscan2
- CLEC2D | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV51992723; called by muse, mutect2, varscan2
- CLEC4C | c.550A>C p.N184H | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.461); catalogued as COSV100665312; called by muse, mutect2, varscan2
- CLEC9A | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs749646888, COSV100872622; called by muse, varscan2
- CLTC | c.3932G>A p.R1311Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV99291466; called by muse, mutect2, varscan2
- CMAS | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.934); catalogued as COSV99982504; called by muse, mutect2, varscan2
- CMC1 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 10/158 reads (6%) | catalogued as COSV58362477; called by muse, mutect2
- CMPK2 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99878578; called by muse, mutect2, varscan2
- CMYA5 | c.6518A>C p.K2173T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs561658301, COSV101483678; called by muse, mutect2, varscan2
- CNBD1 | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101582132; called by muse, mutect2, varscan2
- CNBD2 | c.992T>G p.F331C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100839010, COSV62587016; called by muse, mutect2, varscan2
- CNDP1 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV100722131; called by muse, mutect2, varscan2
- CNGA2 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100323291; called by muse, varscan2
- CNGA4 | c.1021T>A p.S341T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101171697; called by muse, mutect2, varscan2
- CNGB1 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs781104590, COSV51901137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNKSR1 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100836638; called by muse, mutect2, varscan2
- CNKSR1 | c.1924G>A p.E642K (on ENST00000374253 / NM_001297647.2; = p.E635K on NM_006314.3) | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.656); catalogued as COSV100128140, COSV58794669; called by muse, mutect2, varscan2
- CNOT1 | c.6430G>A p.D2144N | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99798917; called by muse, mutect2, varscan2
- CNOT1 | c.3901A>C p.N1301H | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.174); catalogued as COSV99798920; called by muse, mutect2, varscan2
- CNOT10 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV59389936; called by muse, mutect2, varscan2
- CNPPD1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs773704071, COSV56087303; called by muse, mutect2, varscan2
- CNPY1 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as rs753643682, COSV58787130; called by muse, varscan2
- CNRIP1 | c.187T>A p.S63T | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99721049; called by muse, mutect2, varscan2
- CNST | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as rs1279654277, COSV100829764; called by muse, mutect2, varscan2
- CNTN1 | c.1673G>T p.R558M | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100750731; called by muse, mutect2, varscan2
- CNTN1 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100750733; called by muse, mutect2, varscan2
- CNTN2 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100084520; called by muse, mutect2, varscan2
- CNTN3 | c.947-2A>C p.X316_splice | Splice Site (SNP) | VAF 17/65 reads (26%) | catalogued as rs762695137, COSV99722799; called by muse, mutect2, varscan2
- CNTN6 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV63183460; called by muse, mutect2, varscan2
- CNTN6 | c.2545G>T p.E849* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as rs1176820262, COSV63167984, COSV63170441; called by muse, mutect2, varscan2
- CNTNAP4 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56667093; called by muse, mutect2, varscan2
- CNTNAP5 | c.3439C>A p.L1147I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV101442870; called by muse, mutect2, varscan2
- COBL | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.842); catalogued as rs1367067686, COSV99470813; called by muse, mutect2, varscan2
- COG7 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as rs754431741, COSV56150331; called by muse, mutect2, varscan2
- COIL | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV99537877; called by muse, mutect2, varscan2
- COL11A1 | c.4793G>A p.G1598D | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100614254; called by muse, varscan2
- COL11A1 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV62176569; called by muse, mutect2, varscan2
- COL14A1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV52848487; called by muse, mutect2
- COL19A1 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100504699; called by muse, mutect2, varscan2
- COL19A1 | c.1990C>A p.P664T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100504701; called by muse, mutect2, varscan2
- COL23A1 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs555500698, COSV101177745; called by muse, mutect2, varscan2
- COL24A1 | c.2537G>T p.G846V | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748650963, COSV100992757; called by muse, mutect2, varscan2
- COL27A1 | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.049); catalogued as COSV61925038; called by muse, varscan2
- COL27A1 | c.4060C>T p.R1354* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV61923307; called by muse, mutect2
- COL6A3 | c.9445G>A p.E3149K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs138694883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.8870C>T p.A2957V | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1287394484; called by muse, mutect2
- COL6A3 | c.5872G>T p.D1958Y | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV55098709; called by muse, mutect2, varscan2
- COL6A5 | c.6278G>T p.R2093I (on ENST00000312481; = p.R2089I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV99591390, COSV99593814; called by muse, mutect2, varscan2
- COLQ | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101081905; called by muse, mutect2, varscan2
- COP1 | c.2039T>G p.F680C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100442414; called by muse, mutect2, varscan2
- COQ2 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100269837; called by muse, mutect2, varscan2
- COQ8A | c.1146C>A p.S382R | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100825489; called by muse, mutect2, varscan2
- COQ8A | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139900636; called by muse, varscan2
- COX7B | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs1400071124, COSV100968780, COSV64864824; called by muse, mutect2, varscan2
- COX7B2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 53/162 reads (33%) | catalogued as rs1196742833, COSV100259744, COSV57218524; called by muse, mutect2, varscan2
- CPA3 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV99935867; called by muse, mutect2, varscan2
- CPED1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772467238, COSV60010428; called by muse, mutect2, varscan2
- CPNE8 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.052); catalogued as rs150159686; called by muse, mutect2, varscan2
- CPNE8 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100503610, COSV100505107; called by muse, mutect2, varscan2
- CPOX | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749579807, COSV51640003; called by muse, mutect2, varscan2
- CPSF2 | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV100102362, COSV54099588; called by muse, mutect2, varscan2
- CPSF3 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 50/126 reads (40%) | catalogued as rs199913516; called by muse, mutect2, varscan2
- CPTP | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV100027821; called by muse, mutect2, varscan2
- CPXM1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs371262031, COSV66047133; called by muse, varscan2
- CR1L | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as COSV54331990, COSV99686643; called by muse, mutect2, varscan2
- CR2 | c.1898G>T p.G633V | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889493, COSV65508184; called by muse, mutect2, varscan2
- CR2 | c.2005C>A p.L669I | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV100889494; called by muse, mutect2, varscan2
- CRACD | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763160970, COSV99948265; called by muse, mutect2, varscan2
- CRACD | c.3373G>T p.E1125* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99948267; called by muse, mutect2, varscan2
- CRB1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369775002, COSV66328542; called by muse, mutect2, varscan2
- CRB1 | c.3710C>A p.S1237Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100957592, COSV66332475; called by muse, mutect2, varscan2
- CREB3L2 | c.341G>T p.W114L | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100381436; called by muse, mutect2, varscan2
- CRISPLD1 | c.1406G>T p.R469I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100081386; called by muse, varscan2
- CRNKL1 | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 96/294 reads (33%) | catalogued as rs780569934, COSV58548327; called by muse, mutect2, varscan2
- CROT | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs750022928, COSV100519227; called by muse, mutect2, varscan2
- CROT | c.1457C>A p.A486D | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758473204, COSV100519228; called by muse, mutect2, varscan2
- CRTC1 | c.890T>G p.M297R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV100118910; called by muse, mutect2, varscan2
- CRYBA1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs753905999, COSV56601406; called by muse, mutect2, varscan2
- CRYBG1 | c.5444C>A p.S1815Y | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs772247383, COSV100954336; called by muse, mutect2, varscan2
- CSF2RA | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 106/270 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs768192391, COSV62625909; called by muse, mutect2, varscan2
- CSMD1 | c.7910C>T p.T2637M (on ENST00000520002; = p.T2636M on NM_033225.6) | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1184531132, COSV59292521; called by muse, mutect2, varscan2
- CSMD1 | c.7263G>T p.K2421N (on ENST00000520002; = p.K2420N on NM_033225.6) | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as COSV100141376, COSV59365272; called by muse, mutect2, varscan2
- CSMD3 | c.7939G>T p.D2647Y (on ENST00000297405 / NM_001363185.1; = p.D2543Y on NM_052900.3) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99819929; called by muse, mutect2, varscan2
- CSMD3 | c.4633G>T p.E1545* (on ENST00000297405 / NM_001363185.1; = p.E1441* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | catalogued as COSV99819931; called by muse, mutect2, varscan2
- CSMD3 | c.4441C>A p.L1481I (on ENST00000297405 / NM_001363185.1; = p.L1377I on NM_052900.3) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV52228164; called by muse, mutect2, varscan2
- CSMD3 | c.578G>T p.R193I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV52165021, COSV52175503, COSV99819934; called by muse, mutect2, varscan2
- CSTF3 | c.1923A>C p.E641D | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV100123638; called by muse, mutect2, varscan2
- CTAGE6 | c.1377G>T p.E459D | Missense Mutation (SNP) | VAF 59/382 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV101417790; called by muse, mutect2, varscan2
- CTNNA3 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV101044329; called by muse, mutect2, varscan2
- CTNNA3 | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100373126; called by muse, mutect2, varscan2
- CTNNAL1 | c.519+1G>A p.X173_splice | Splice Site (SNP) | VAF 61/171 reads (36%) | catalogued as COSV100336213; called by muse, mutect2, varscan2
- CTR9 | c.1808C>A p.S603Y | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100797207; called by muse, mutect2, varscan2
- CTR9 | c.2616G>T p.K872N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV100797208, COSV63728990; called by muse, mutect2, varscan2
- CTSC | c.1181G>T p.R394I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV99910405; called by muse, mutect2, varscan2
- CTTN | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 35/114 reads (31%) | catalogued as COSV57235346; called by muse, mutect2, varscan2
- CUBN | c.6408G>T p.Q2136H | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100911746; called by muse, mutect2, varscan2
- CUBN | c.6157C>T p.L2053F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs751834059, COSV100911747, COSV64726423; called by muse, mutect2, varscan2
- CUBN | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs746956601, COSV100911750; called by muse, mutect2, varscan2
- CUL2 | c.1192T>G p.L398V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV101038966; called by muse, varscan2
- CUL5 | c.2131C>T p.R711* | Nonsense Mutation (SNP) | VAF 54/156 reads (35%) | catalogued as COSV67608755; called by muse, varscan2
- CUL7 | c.3909G>T p.Q1303H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99537517; called by muse, mutect2
- CWF19L2 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 42/132 reads (32%) | catalogued as COSV56511095; called by muse, mutect2, varscan2
- CXCL11 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 13/214 reads (6%) | catalogued as COSV100134867, COSV60666200; called by muse, mutect2
- CXCL11 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs377189872, COSV60666552; called by muse, mutect2, varscan2
- CXCL11 | c.8T>G p.V3G | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV100134869, COSV60666604; called by muse, mutect2
- CXCL9 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.069); catalogued as COSV53579166, COSV99345607; called by muse, mutect2, varscan2
- CXCR3 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV101031507; called by muse, mutect2
- CXorf66 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.895); catalogued as COSV100983794; called by muse, mutect2, varscan2
- CXorf66 | c.513A>C p.K171N | Missense Mutation (SNP) | VAF 136/338 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.743); catalogued as COSV100983796; called by muse, varscan2
- CXorf66 | c.243-1G>T p.X81_splice | Splice Site (SNP) | VAF 50/147 reads (34%) | catalogued as COSV100983797; called by muse, mutect2, varscan2
- CXorf66 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV65168941; called by muse, mutect2
- CYB5R1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.393); catalogued as rs375559693; called by muse, mutect2, varscan2
- CYBRD1 | c.818G>T p.R273I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100361092; called by muse, mutect2
- CYC1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769424627, COSV100010134; called by muse, mutect2, varscan2
- CYLC2 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100872297; called by muse, mutect2
- CYP27A1 | c.1211C>A p.S404Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs775495879, COSV99298252, COSV99298454; called by muse, mutect2, varscan2
- CYP2A13 | c.897C>A p.F299L | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); catalogued as COSV100386572; called by muse, mutect2, varscan2
- CYP2W1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as rs991930893, COSV100417053; called by muse, mutect2, varscan2
- CYP4F2 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV55619012; called by muse, mutect2, varscan2
- CYP4Z1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV100497445; called by muse, mutect2, varscan2
- CYP4Z1 | c.1350G>T p.R450S | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100497449; called by muse, mutect2, varscan2
- CYP7A1 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100052080; called by muse, mutect2, varscan2
- CYTH3 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV63440607; called by muse, mutect2, varscan2
- CZIB | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV99597991; called by muse, mutect2, varscan2
- DAAM1 | c.1797G>T p.K599N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV100658018; called by muse, mutect2, varscan2
- DACH2 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100912238, COSV64164505; called by muse, mutect2, varscan2
- DAGLB | c.1529G>T p.R510I | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV99765579; called by muse, mutect2, varscan2
- DBR1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV53429705, COSV53429918; called by muse, mutect2, varscan2
- DCAF1 | c.1979G>C p.S660T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV60045110; called by muse, mutect2, varscan2
- DCAF4L2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293407129, COSV100150573, COSV60476409; called by muse, mutect2, varscan2
- DCAF8L1 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 36/111 reads (32%) | catalogued as COSV101491364; called by muse, mutect2, varscan2
- DCC | c.1541C>A p.S514Y | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497330; called by muse, mutect2, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV59088081; called by muse, mutect2, varscan2
- DCDC1 | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100662431; called by muse, mutect2, varscan2
- DCHS1 | c.6805G>A p.D2269N | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55031393; called by muse, mutect2, varscan2
- DCHS2 | n.799+1G>T | Splice Site (SNP) | VAF 96/277 reads (35%) | catalogued as COSV100250546; called by muse, mutect2, varscan2
- DCLK3 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373605259, COSV69363137; called by muse, mutect2, varscan2
- DCSTAMP | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs201462772; called by muse, mutect2, varscan2
- DCTN3 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1020680836, COSV99426652; called by muse, mutect2, varscan2
- DCUN1D1 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as rs1402995089, COSV99489600; called by muse, mutect2, varscan2
- DCXR | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as COSV100178766; called by muse, mutect2, varscan2
- DDB1 | c.1690A>G p.I564V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.206); catalogued as COSV100074114; called by muse, mutect2, varscan2
- DDHD2 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV101240437; called by muse, mutect2, varscan2
- DDHD2 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs552644015, COSV101240440; called by muse, varscan2
- DDIAS | c.578T>A p.L193H | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV100230936; called by muse, mutect2, varscan2
- DDIT4L | c.215A>C p.K72T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.133); catalogued as COSV99913767; called by muse, mutect2, varscan2
- DDX10 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100488795; called by muse, mutect2, varscan2
- DDX10 | c.2039G>T p.R680I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV59433196; called by muse, mutect2, varscan2
- DDX11 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1430203525, COSV99298721; called by muse, mutect2, varscan2
- DDX21 | c.2049T>G p.F683L | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV100826449; called by muse, mutect2, varscan2
- DDX23 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.735); catalogued as COSV100339493; called by muse, mutect2, varscan2
- DDX24 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV100427766; called by muse, mutect2, varscan2
- DDX50 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV65291862; called by muse, mutect2, varscan2
- DDX60L | c.3559A>C p.N1187H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99486670; called by muse, mutect2, varscan2
- DDX60L | c.1256G>T p.R419I | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV99486671, COSV99488756; called by muse, mutect2, varscan2
- DDX60L | c.1122A>C p.E374D | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99486672; called by muse, mutect2, varscan2
- DEFB112 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.031); catalogued as COSV100452080; called by muse, mutect2, varscan2
- DEFB118 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV53620849; called by muse, mutect2, varscan2
- DEFB136 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.802); catalogued as COSV101198577, COSV66363841; called by muse, mutect2, varscan2
- DENND10 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as rs1294577516, COSV57459918, COSV57459982; called by muse, mutect2, varscan2
- DENR | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV99757219; called by muse, mutect2, varscan2
- DEPDC1 | c.1395C>A p.F465L | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100920168; called by muse, mutect2, varscan2
- DEPDC1 | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100920169; called by muse, mutect2, varscan2
- DEPDC5 | c.2840C>A p.S947Y (on ENST00000400246; = p.S1016Y on NM_014662.5) | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.12); catalogued as COSV99833964; called by muse, mutect2, varscan2
- DEUP1 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 43/138 reads (31%) | catalogued as COSV99976446; called by muse, mutect2, varscan2
- DGKB | c.1175G>T p.R392I | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV99335185; called by muse, mutect2, varscan2
- DGKE | c.1493C>A p.P498H | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM149472, COSV99400606; called by muse, mutect2, varscan2
- DGKH | c.3613C>A p.L1205I (on ENST00000337343 / NM_178009.5; = p.S1161Y on NM_152910.6) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54939860; called by muse, mutect2, varscan2
- DGKI | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 41/125 reads (33%) | catalogued as COSV55948500, COSV99931690; called by muse, mutect2, varscan2
- DGKI | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99931693; called by muse, mutect2, varscan2
- DGKI | c.739-1G>T p.X247_splice | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as COSV55972362; called by muse, mutect2, varscan2
- DGKI | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV99931696; called by muse, mutect2, varscan2
- DGLUCY | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs767173655, COSV99823851; called by muse, mutect2, varscan2
- DHDH | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV55482454; called by muse, mutect2, varscan2
- DHFR2 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1440371200, COSV58936656; called by muse, mutect2, varscan2
- DHX32 | c.1199T>G p.F400C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99501227; called by muse, mutect2, varscan2
- DHX40 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV99232611; called by muse, mutect2, varscan2
- DHX57 | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV54882351, COSV99770019; called by muse, mutect2, varscan2
- DIAPH2 | c.2838G>T p.K946N | Missense Mutation (SNP) | VAF 98/312 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100229827; called by muse, mutect2, varscan2
- DIPK1A | c.446T>G p.F149C | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100941900; called by muse, mutect2, varscan2
- DISP3 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 88/114 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748159081, COSV53826680; called by muse, mutect2, varscan2
- DIXDC1 | c.1047G>T p.E349D (on ENST00000440460 / NM_001037954.4; = p.E138D on NM_033425.4) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1555173918, COSV100179987; called by muse, mutect2, varscan2
- DKK3 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as COSV100484871; called by muse, mutect2, varscan2
- DLEC1 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as COSV100341038; called by muse, mutect2, varscan2
- DLGAP5 | c.1190A>C p.K397T | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99903554; called by muse, mutect2, varscan2
- DMD | c.7667G>T p.R2556I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV58889726, COSV58946219; called by muse, mutect2, varscan2
- DMD | c.5201C>A p.T1734K | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV100817122; called by muse, mutect2, varscan2
- DMD | c.4701G>T p.E1567D | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100817124; called by muse, mutect2, varscan2
- DMD | c.3397G>T p.E1133* | Nonsense Mutation (SNP) | VAF 65/159 reads (41%) | catalogued as CM068537, COSV100817127, COSV63764235; called by muse, mutect2, varscan2
- DMD | c.2293-1G>T p.X765_splice | Splice Site (SNP) | VAF 20/55 reads (36%) | catalogued as CS140179, CS982161, COSV100817130; called by muse, mutect2, varscan2
3,061 further variants in this file (2,344 protein-altering or splice-affecting, 603 silent, 114 other) are not listed here.
